Gene-level copy-number profile of tumor specimen TCGA-12-0827-01A from TCGA case TCGA-12-0827, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.6 years (14,093 days).
Specimen TCGA-12-0827-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.87dcb43c-18a1-4d1b-8fb0-717350c3703f.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,377 have no estimate.
https://portal.gdc.cancer.gov/files/246bb50f-3f69-4afc-86f9-246cf392d945

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 17,158; copy number 2: 34,816; copy number 3: 2,549; copy number 4: 674; copy number 5: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0827-01A-01D-0384-01): tumor purity 0.58, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,967,752–24,905,735, 27 genes: CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5.
- chr9:25,676,389–26,118,408, 4 genes: TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr9:27,102,630–27,230,174, 3 genes (within-gene range 0–1): AL355432.1, TEK, RNA5SP280.
- chr21:23,090,028–23,119,903, 3 genes: ZNF299P, MSANTD2P1, AP001255.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:32,043,261–32,278,382, 12 genes, copy number 5 (within-gene range 1–5): SLC5A1, AP1B1P1, Z83839.1, AP1B1P2, Z83839.2, C22orf42, AL008723.1, AL008723.3, RFPL2, IGLCOR22-1, SLC5A4-AS1, SLC5A4.

Autosomal genes at a single copy (total copy number 1): 17,158. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
